Somatic mutation profile of tumor specimen MP2PRT-PASRLU-TMP1-A (aliquot MP2PRT-PASRLU-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASRLU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,657 days).
Specimen MP2PRT-PASRLU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fb92a7b-48b7-4abf-a3a4-6f52cd871784.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRLU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRLU-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c5077a8-e00b-4ae6-8982-45f255c44f4a

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOXE3 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs774243681, COSV59075367, COSV59078290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.6178C>T p.R2060C | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs587778078, COSV53732724; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- ATP13A5 | c.1857C>G p.F619L | Missense Mutation (SNP) | VAF 102/349 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV60873626; called by muse, mutect2, varscan2
- MUSK | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.057); catalogued as rs867005027, COSV51894909; called by muse, mutect2
- NAA11 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 42/455 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770764114, COSV54514347, COSV54516285; called by muse, mutect2
- NRAS | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54738004, COSV54746465; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 181/581 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1434852395, COSV52755128; called by muse, mutect2, varscan2
- FREM2 | c.6805T>A p.S2269T | Missense Mutation (SNP) | VAF 88/251 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HECTD1 | c.6793C>T p.P2265S | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IGHV2-70 | chr14:106770572 CTGTGGTAT>TCCTGTGG | Missense Mutation (DEL) | VAF 61/182 reads (34%) | called by pindel, varscan2*
- IGHV3-48 | c.352_353insGGGGAG | In Frame Ins (INS) | VAF 3/35 reads (9%) | called by mutect2, pindel
- IGLV4-69 | chr22:22031468 ATTCACA>CG | Missense Mutation (DEL) | VAF 76/89 reads (85%) | called by pindel, varscan2*
- KLHL20 | c.720A>C p.K240N | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- MUC6 | c.4405C>G p.Q1469E | Missense Mutation (SNP) | VAF 195/826 reads (24%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, varscan2
- NYAP2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PTPN21 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACCSL | c.930G>T p.L310= | Silent (SNP) | VAF 22/402 reads (5%) | catalogued as COSV66581304; called by muse, mutect2
- AGR2 | c.423C>T p.I141= | Silent (SNP) | VAF 25/396 reads (6%) | called by muse, mutect2
- ARHGAP45 | c.378C>T p.F126= | Silent (SNP) | VAF 143/541 reads (26%) | catalogued as rs199753504; called by muse, mutect2
- EVC | c.1872C>T p.G624= | Silent (SNP) | VAF 25/333 reads (8%) | catalogued as rs374432399; called by muse, mutect2
- IFNL2 | c.475C>T p.L159= | Silent (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- ZNF85 | c.1314C>T p.S438= | Silent (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
